Gene-level copy-number profile of tumor specimen TCGA-DG-A2KJ-01A from TCGA case TCGA-DG-A2KJ, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, large cell, nonkeratinizing, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IIIB; Tumor grade: G3; Age at diagnosis: 50.5 years (18,453 days).
Specimen TCGA-DG-A2KJ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-CESC.78d79502-304f-49e4-9845-32675036e06b.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-DG-A2KJ-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 823 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/feeb4535-a3de-427a-b35f-55b8f8fb5d12

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 67; copy number 1: 21,427; copy number 2: 30,957; copy number 3: 3,920; copy number 4: 2,083; copy number 5: 1,116; copy number 6: 195; copy number 7: 9; copy number 9: 26.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-DG-A2KJ-01A-11D-A18H-01): tumor purity 0.61, ploidy 1.75, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 67 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:186,208,979–186,726,722, 10 genes (within-gene range 0–1): KLKB1, F11, F11-AS1, AC109517.1, SLC25A5P6, AC018709.1, RNU6-1055P, MTNR1A, FAT1, AC107050.1.
- chr5:152,618,965–153,223,543, 1 gene (within-gene range 0–2): LINC01470.
- chr10:87,341,685–89,420,997, 56 genes: LINC00863, NUTM2D, NPAP1P3, CTSLP1, FAM245A, AL355334.1, AL355334.2, MIR4678, MINPP1, AL138767.2, AL138767.3, AL138767.1, RPS26P38, PAPSS2, ATAD1, CFL1P1, RN7SL78P, KLLN, PTEN, AC063965.2, RPL11P3, AC063965.1, MED6P1, AL353149.1, RNLS, Y_RNA, LIPJ, RPL7P34, LIPF, NAPGP1, LIPK, KRT8P38, LIPN, RCBTB2P1, LIPM, ANKRD22, PTCD2P2, STAMBPL1, ACTA2-AS1, ACTA2, AL157394.3, FAS, AL157394.2, AL157394.1, MIR4679-2, MIR4679-1, AL513533.1, CH25H, LIPA, IFIT2, AL353751.1, IFIT3, IFIT6P, IFIT1B, IFIT1, IFIT5.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,346 genes in 11 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:5,103,629–7,251,980, 34 genes, copy number 5 (within-gene range 4–5): LYRM4, MIR3691, FARS2, AL121978.1, AL021328.1, HNRNPA1P37, AL022097.1, AL136968.2, AL136968.1, AL136307.1, RN7SL221P, PKMP5, NRN1, F13A1, MIR7853, MIR5683, LY86-AS1, SNAPC5P1, AL162719.1, CNN3P1, LY86, AL031123.2, AL031123.3, AL031123.1, AL031123.4, AL031123.5, AL136361.1, BTF3P7, AL158817.1, RN7SL554P, AL139390.1, RREB1, AL355336.1, Y_RNA.
- chr6:9,596,110–21,232,404, 174 genes, copy number 5 (within-gene range 2–5) (broad region; genes not listed).
- chr6:86,432,244–96,215,612, 119 genes, copy number 5–9 (within-gene range 4–9) (broad region; genes not listed).
- chr6:99,918,519–100,464,921, 8 genes, copy number 7: MCHR2, MCHR2-AS1, NPM1P38, AL080285.2, PRDX2P4, AL080285.1, SIM1, SIM1-AS1.
- chr6:100,530,276–100,531,052, 1 gene, copy number 7: Z86062.1.
- chr6:104,936,616–110,180,004, 104 genes, copy number 6 (broad region; genes not listed).
- chr12:43,835,967–44,389,762, 1 gene, copy number 5 (within-gene range 2–5): TMEM117.
- chr12:44,244,394–44,921,848, 5 genes, copy number 5 (within-gene range 2–5): AC025030.2, AC025030.1, AC025253.1, AC025253.2, NELL2.
- chr12:46,183,063–47,943,048, 46 genes, copy number 5: SLC38A1, AC025031.3, SLC38A2, AC025031.2, AC008014.1, AC025031.1, AC025031.4, AC025031.5, AC008035.1, OR7A19P, MARK3P1, SLC38A4, AC079906.1, AMIGO2, PCED1B, IFITM3P6, MIR4698, PCED1B-AS1, AC008083.2, AC008083.3, AC008083.4, PPIAP45, AC008083.1, LINC02416, MIR4494, LINC02156, ADI1P3, AC003686.1, AC004486.1, RPAP3, AC004241.3, AC004241.1, ENDOU, AC004241.5, AC004241.2, RAPGEF3, SLC48A1, AC004241.4, HDAC7, AC004466.1, AC004466.3, AC004466.2, LINC02354, VDR, AC121338.1, AC121338.2.
- chr12:50,504,985–55,322,364, 235 genes, copy number 5–9 (broad region; genes not listed).
- chr20:38,601,934–64,313,132, 619 genes, copy number 5–6 (within-gene range 4–6) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 19,006. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
